Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QM, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QM-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Thymoma, type AB
malignant 8582/3

Site: ^{chc}Thymus C37.9

^{path}Mediastinum NOS C88.3

4/2/14

Macroscopic examination

A piece of thymectomy weighing 355 g and measuring 11 x 9 x 5 cm nodular lesion with a 10 x 8 x 4 cm with the cutting aspect fleshy , beige , homogeneous, lobulated .

Histopathological examination :

1) tumor of the mediastinum :

The tumor is made up of spindle cells , regular, frequently grouped by small short beams . The second contingent is made of lymphocytes small size , which appear intimately involved in epithelial proliferation. The proliferation divided by arches is formed by spindle-shaped cells, pseudo- fibroblasts. Absence of clear perivascular spaces. No evidence of medullary differentiation .

Presence at some fibrous septa rearrangements with macrophage foamy histiocytes type .

After immunohistochemistry , epithelial cells express cytokeratin AE1/AE3 , cytokeratin KL1 , cytokeratin 5/6 . They do not express cytokeratin 7 or CD20. The cells express CD3 , CD1A the . Spindle cells and pseudo- fibroblasts express EMA.

2) pleural lesion :

It is a fragment of vascular connective- tissue .

Conclusion :

Thymoma sub AB type, 10 cm long axis , with no evidence of capsular invasion. Stage I

Complete surgical resection.

[page 2 of 2]
Criteria	hw 12/18/13	Yes	No

Source: NCI Genomic Data Commons file cf245d54-2a2e-449a-91b8-dd0d41c73ec7 (TCGA-4V-A9QM.542FEBB4-FF25-4B2C-8202-172643C48110.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).